Gene-level copy-number profile of tumor specimen TCGA-D6-8568-01A from TCGA case TCGA-D6-8568, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 62.4 years (22,796 days).
Specimen TCGA-D6-8568-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.b7770bb6-ccf0-4fb0-9da2-88317719c1f3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D6-8568-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bcfac970-e0b8-4609-b003-e998ef73f005

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,356; copy number 2: 45,484; copy number 3: 1,800; copy number 4: 3,156; copy number 5: 143; copy number 6: 171; copy number 7: 710.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D6-8568-01A-11D-2390-01): tumor purity 0.38, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,024 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 7 (broad region; genes not listed).
- chr16:46,469,341–57,971,128, 308 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr16:79,676,048–80,167,577, 5 genes, copy number 5 (within-gene range 4–5): LINC01229, MAFTRR, LINC01228, AC092130.1, AC022166.1.
- chr16:80,179,129–80,180,682, 1 gene, copy number 5: AC022166.2.

Autosomal genes at a single copy (total copy number 1): 7,141. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
